Somatic mutation profile of tumor specimen HCM-CSHL-0839-C34-06A (aliquot HCM-CSHL-0839-C34-06A-11D-A85L-36) from HCMI case HCM-CSHL-0839-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,837 days).
Specimen HCM-CSHL-0839-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de864cd9-eef8-4d6d-8f28-16c28b409223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0839-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0839-C34-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80efb55f-ff7b-47d9-86f3-1579fc7c2ae6

The open-access MAF lists 169 somatic variants for this specimen: 124 protein-altering or splice-affecting, 36 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 36, Nonsense Mutation 14, Intron 6, 3'UTR 2, Splice Site 1, Frame Shift Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 40/458 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2
- ETFDH | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780768015, CM083497, COSV100306677; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 38/319 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100602107; called by muse, mutect2, varscan2
- AFF2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV53989330; called by muse, mutect2
- ANK2 | c.8257G>A p.E2753K | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as COSV100002152; called by muse, mutect2, varscan2
- ARCN1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50615450; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1168G>A p.E390K (on ENST00000272238 / NM_001039362.2; = p.E344K on NM_144583.4) | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs779590851, COSV55351622; called by muse, mutect2, varscan2
- BARHL1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1240260230; called by muse, mutect2, varscan2
- BASP1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 53/420 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs529077079, COSV59472808; called by muse, mutect2, varscan2
- C15orf48 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100721085; called by muse, mutect2
- C20orf144 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 40/437 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.434); catalogued as rs776940228; called by muse, mutect2, varscan2
- C5orf22 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57599158; called by muse, mutect2, varscan2
- CCDC183 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100565982, COSV62012082; called by muse, mutect2
- CHST15 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); catalogued as COSV100655388; called by muse, mutect2, varscan2
- CTNS | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs1033304034; called by muse, mutect2, varscan2
- DDX58 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV65882606; called by muse, mutect2, varscan2
- DMGDH | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 54/372 reads (15%) | catalogued as rs199723565; called by muse, mutect2
- EEF1A1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58548609, COSV58550358; called by muse, mutect2
- ERRFI1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs980250925, COSV66310844, COSV66311405; called by muse, varscan2
- GOLPH3 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 30/304 reads (10%) | catalogued as COSV54059646, COSV54059831; called by muse, mutect2, varscan2
- GPR52 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99267936; called by muse, mutect2
- GPSM1 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs782626806, COSV52517439; called by muse, mutect2, varscan2
- HBP1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 56/377 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs1486646509; called by muse, mutect2, varscan2
- HSPD1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV61443427, COSV61446053; called by muse, mutect2, varscan2
- KLHL3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778670860, COSV59053906; called by muse, mutect2, varscan2
- KMT5B | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 51/379 reads (13%) | catalogued as COSV58564192; called by muse, mutect2, varscan2
- LCMT2 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2
- LMBR1 | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV62219118; called by muse, mutect2, varscan2
- LRRTM4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs764914907; called by muse, mutect2, varscan2
- LY75-CD302 | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as rs916021125; called by muse, mutect2, varscan2
- LYPLA1 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV57606934; called by muse, mutect2, varscan2
- MACF1 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 37/264 reads (14%) | catalogued as COSV57103368; called by muse, mutect2, varscan2
- MAP3K12 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as rs1193076395; called by muse, mutect2, varscan2
- MBOAT1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs184491612; called by muse, mutect2
- MUC17 | c.5899C>G p.P1967A | Missense Mutation (SNP) | VAF 111/585 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as rs568723888, COSV60295022; called by muse, mutect2, varscan2
- MYEF2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 27/383 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs34619312; called by muse, mutect2
- NHP2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1296058145; called by muse, varscan2
- NID1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.048); catalogued as rs149309893, COSV51622376; called by muse, mutect2, varscan2
- NLN | c.1743G>C p.L581F | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as COSV101114427; called by muse, mutect2, varscan2
- NRXN3 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | catalogued as COSV73586295; called by muse, mutect2, varscan2
- NRXN3 | c.2823C>G p.I941M (on ENST00000335750 / NM_001330195.2; = p.I568M on NM_004796.6) | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV59730982; called by muse, mutect2, varscan2
- OTUD4 | c.1766C>G p.S589C (on ENST00000447906 / NM_001366057.1; = p.S524C on NM_001102653.1) | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs777213342; called by muse, mutect2, varscan2
- PCDH10 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as COSV52092488; called by muse, mutect2, varscan2
- PCLO | c.6889G>A p.E2297K | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV61633973, COSV61674490; called by muse, mutect2, varscan2
- PDE5A | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV53347571; called by muse, mutect2, varscan2
- PHIP | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 17/241 reads (7%) | catalogued as COSV99245115; called by muse, mutect2
- PIGV | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as rs368069947; called by muse, varscan2
- REC8 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757113882; called by muse, varscan2
- RNASE10 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60517408; called by muse, mutect2, varscan2
- RTKN | c.148C>T p.R50W (on ENST00000272430 / NM_001015055.2; = p.R37W on NM_033046.2) | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751247798; called by muse, mutect2, varscan2
- RYR2 | c.14656-1G>C p.X4886_splice | Splice Site (SNP) | VAF 12/192 reads (6%) | catalogued as COSV100769970, COSV63688388; called by muse, mutect2
- SALL1 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV51758759; called by muse, mutect2, varscan2
- SNCAIP | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54405893; called by muse, mutect2, varscan2
- STK16 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs751098957, COSV50280426; called by muse, mutect2, varscan2
- SVOPL | c.1397C>A p.S466* (on ENST00000419765; = p.S314* on NM_174959.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/270 reads (18%) | catalogued as COSV55989290; called by muse, mutect2, varscan2
- TDG | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753641238, COSV99904318; called by muse, mutect2
- TNFSF4 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV99919462; called by muse, mutect2, varscan2
- TP53BP2 | c.1430C>A p.S477Y (on ENST00000343537 / NM_001031685.3; = p.S348Y on NM_005426.2) | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV100636878; called by mutect2, varscan2
- TRIM49 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV61670585; called by muse, mutect2
- TTC26 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs751696700; called by muse, mutect2
- TTI2 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 47/371 reads (13%) | catalogued as COSV62452154; called by muse, mutect2, varscan2
- ZNF106 | c.4559A>G p.D1520G | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs749557418; called by muse, mutect2, varscan2
- ZNF711 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV52151015, COSV52154260; called by muse, mutect2
- ABCA8 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCC10 | c.2365G>C p.E789Q (on ENST00000372530 / NM_001198934.2; = p.E761Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ACTN4 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ADAM17 | c.714C>G p.Y238* | Nonsense Mutation (SNP) | VAF 35/293 reads (12%) | called by muse, mutect2, varscan2
- ADGRG3 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- APLF | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATAD1 | c.654T>A p.S218R | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ATL3 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 114/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATP2C1 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- BRAP | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BVES | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C17orf78 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC191 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC39 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCER2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COMMD2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- CRTC2 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 45/546 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2
- CUL4A | c.818G>T p.R273I (on ENST00000375440 / NM_001008895.4; = p.R173I on NM_003589.3) | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DUSP16 | c.1212C>G p.I404M | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF3B | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EPB41L4B | c.2299C>T p.L767= | Splice Region (SNP) | VAF 30/311 reads (10%) | called by muse, mutect2
- EPHA1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 79/492 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM149B1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- GCM1 | c.943A>C p.N315H | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- GIT2 | c.1231A>G p.N411D (on ENST00000355312 / NM_057169.5; = p.N413D on NM_014776.5) | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR137C | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRAMD1B | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KIAA0319 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- LMTK2 | c.2076G>C p.K692N | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPGAT1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LZTS1 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2
- MAP3K13 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MUC12 | c.12890C>G p.S4297* (on ENST00000379442; = p.S4154* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 44/101 reads (44%) | called by mutect2, varscan2
- NFE2L3 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIM1K | c.1112T>A p.I371N | Missense Mutation (SNP) | VAF 50/489 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- NIPBL | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PKDCC | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PNN | c.2117G>C p.R706T | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POM121 | c.2279_2289del p.L760Hfs*13 (on ENST00000434423; = p.L495Hfs*13 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 122/917 reads (13%) | called by mutect2, pindel, varscan2
- PUM2 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RIPK2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- RLN1 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RPE65 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- RPRD1B | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCGB1A1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 26/199 reads (13%) | called by mutect2, varscan2
- SELENOK | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SPAG17 | c.5680G>A p.E1894K | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2
- ST7 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 68/275 reads (25%) | called by muse, mutect2, varscan2
- SVEP1 | c.10006G>C p.E3336Q | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TAF4 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 27/338 reads (8%) | called by muse, mutect2
- TBCD | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2
- TFAP2A | c.255C>A p.N85K (on ENST00000482890; = p.N77K on NM_001032280.3) | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TOR1AIP1 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 37/470 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2
- UBR5 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UBXN1 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 55/537 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2
- UQCC1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZBED4 | c.1954C>T p.H652Y | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZFHX4 | c.1215A>C p.E405D | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.024); called by muse, mutect2
- ZFP92 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 126/732 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, varscan2
- ZNF777 | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- AHNAK | c.14091C>T p.I4697= | Silent (SNP) | VAF 60/472 reads (13%) | catalogued as rs375130667; called by muse, mutect2, varscan2
- ARHGEF4 | c.790C>T p.L264= | Silent (SNP) | VAF 61/469 reads (13%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.408G>A p.L136= | Silent (SNP) | VAF 44/359 reads (12%) | called by muse, mutect2, varscan2
- CDH10 | c.1842G>A p.L614= | Silent (SNP) | VAF 31/330 reads (9%) | catalogued as COSV100050337, COSV52581148; called by muse, mutect2, varscan2
- CYP27C1 | c.519C>T p.N173= | Silent (SNP) | VAF 32/409 reads (8%) | catalogued as rs372803782; called by muse, mutect2
- CYP4F8 | c.63C>T p.L21= | Silent (SNP) | VAF 70/329 reads (21%) | called by muse, mutect2, varscan2
- DGKZ | c.2484G>A p.P828= (on ENST00000454345 / NM_001105540.2; = p.P640= on NM_003646.4) | Silent (SNP) | VAF 25/230 reads (11%) | catalogued as rs376231459; called by muse, mutect2, varscan2
- DPEP1 | c.420G>A p.V140= | Silent (SNP) | VAF 73/437 reads (17%) | called by muse, mutect2, varscan2
- ECI2 | c.1184G>A p.*395= (on ENST00000380118 / NM_206836.3; = p.*365= on NM_006117.2) | Silent (SNP) | VAF 27/228 reads (12%) | catalogued as rs767036448; called by muse, mutect2, varscan2
- EP400 | c.6123C>G p.V2041= | Silent (SNP) | VAF 89/410 reads (22%) | called by muse, mutect2, varscan2
- GAP43 | c.75C>T p.I25= | Silent (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- GRK1 | c.363C>G p.L121= | Silent (SNP) | VAF 48/449 reads (11%) | catalogued as COSV59554365; called by muse, mutect2, varscan2
- GZMH | c.18C>T p.L6= | Silent (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- HERC1 | c.12762G>A p.L4254= | Silent (SNP) | VAF 32/261 reads (12%) | called by muse, mutect2, varscan2
- HSPG2 | c.264G>A p.V88= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as rs1403049431; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1443C>T p.Y481= | Silent (SNP) | VAF 39/347 reads (11%) | catalogued as rs777536426, COSV56293571; ClinVar: benign; called by muse, mutect2, varscan2
- IRF4 | c.36C>T p.F12= | Silent (SNP) | VAF 51/414 reads (12%) | catalogued as COSV66704496; called by muse, varscan2
- KCNJ14 | c.30C>G p.L10= | Silent (SNP) | VAF 60/306 reads (20%) | catalogued as rs928639669, COSV53519720; called by muse, mutect2, varscan2
- LAMP2 | c.933C>T p.F311= | Silent (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2, varscan2
- MAF | c.741C>T p.H247= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs751341494; called by muse, mutect2, varscan2
- MCAM | c.75C>G p.P25= | Silent (SNP) | VAF 27/240 reads (11%) | catalogued as rs779647125; called by muse, mutect2, varscan2
- MEN1 | c.1668C>G p.L556= | Silent (SNP) | VAF 59/470 reads (13%) | called by muse, mutect2, varscan2
- NOD2 | c.2226C>T p.L742= | Silent (SNP) | VAF 65/460 reads (14%) | catalogued as rs765131217, COSV100318445; called by muse, mutect2, varscan2
- NUP98 | c.4854G>A p.E1618= (on ENST00000359171 / NM_001365126.1; = p.E1601= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 46/350 reads (13%) | called by muse, mutect2, varscan2
- ODF1 | c.111C>T p.C37= | Silent (SNP) | VAF 44/346 reads (13%) | catalogued as rs144503717; called by muse, mutect2, varscan2
- OR13C2 | c.642C>A p.I214= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as COSV73377733; called by muse, mutect2, varscan2
- OSCP1 | c.1140C>T p.D380= (on ENST00000356637 / NM_001330493.1; = p.D370= on NM_145047.5) | Silent (SNP) | VAF 28/256 reads (11%) | catalogued as rs748276524, COSV52487938; called by muse, mutect2, varscan2
- PIP5K1C | c.1326G>C p.T442= | Silent (SNP) | VAF 69/319 reads (22%) | called by mutect2, varscan2
- QRICH1 | c.1014C>T p.N338= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as rs558954411, COSV62614559; called by muse, mutect2, varscan2
- SEMA3A | c.738C>T p.F246= | Silent (SNP) | VAF 27/386 reads (7%) | catalogued as COSV99545587; called by muse, mutect2
- SETX | c.4557C>G p.L1519= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- SHCBP1L | c.1071C>T p.R357= | Silent (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- SOWAHA | c.951G>C p.R317= | Silent (SNP) | VAF 62/459 reads (14%) | called by muse, mutect2, varscan2
- SOX30 | c.525C>T p.L175= | Silent (SNP) | VAF 59/407 reads (14%) | called by muse, mutect2, varscan2
- SYNE2 | c.19773G>A p.L6591= | Silent (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- TBCD | c.2151C>T p.I717= | Silent (SNP) | VAF 46/533 reads (9%) | called by muse, mutect2
- ARRB2 | c.*99dup | 3'UTR (INS) | VAF 40/357 reads (11%) | called by mutect2, pindel, varscan2
- BTBD7 | c.1162+5324G>T | Intron (SNP) | VAF 61/501 reads (12%) | called by muse, mutect2, varscan2
- COBL | c.1096+2091C>T | Intron (SNP) | VAF 48/253 reads (19%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5938C>T | 3'UTR (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2, varscan2
- DST | c.4297-3537G>A | Intron (SNP) | VAF 37/316 reads (12%) | catalogued as rs1390801517, COSV55044002; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22222T>G | Intron (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- NRSN1 | c.190-4383C>A | Intron (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- PCID2 | c.36+554G>A | Intron (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- TMEM8B | c.-721C>T | 5'UTR (SNP) | VAF 49/352 reads (14%) | called by muse, mutect2, varscan2
